Somatic mutation profile of tumor specimen HCM-BROD-0019-C25-01B (aliquot HCM-BROD-0019-C25-01B-01D-A80U-36) from HCMI case HCM-BROD-0019-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G1; Age at diagnosis: 80.6 years (29,434 days).
Specimen HCM-BROD-0019-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60193865-c6d2-4212-9596-213a5b61fbb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0019-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0019-C25-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88e0e930-2ca0-4604-976e-df9fda3c76d9

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 57/662 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- HECW1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 42/459 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs779347290, COSV101223022, COSV67831867; called by muse, mutect2
- PAOX | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 23/375 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1402242327, COSV53371471, COSV53372036; called by muse, mutect2
- RP1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 61/754 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886062989, COSV55112474; ClinVar: uncertain significance; called by muse, mutect2
- RS1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.57); catalogued as rs745526075, COSV66107349; called by muse, mutect2, varscan2
- SMAD4 | c.295T>A p.W99R | Missense Mutation (SNP) | VAF 29/692 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61697064; called by muse, mutect2
- ST6GAL2 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 52/684 reads (8%) | PolyPhen benign (0.003); catalogued as rs1260390177, COSV64532749; called by muse, mutect2
- ZNF335 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 49/662 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1258156157; called by muse, mutect2
- ZSCAN29 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147749773; called by muse, mutect2
- ADAM33 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 21/549 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- GPRASP2 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2
- HINFP | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- HMGB4 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 36/525 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNF1B | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 34/760 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- IL1F10 | c.449A>G p.Q150R | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PASK | c.1472A>C p.N491T | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- PLXNB2 | c.3745T>C p.C1249R | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- QSER1 | c.4384A>G p.S1462G (on ENST00000399302; = p.S1591G on NM_001076786.3) | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); called by muse, mutect2
- TNR | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 45/541 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.121); called by muse, mutect2
- TUBB6 | c.1178C>G p.A393G | Missense Mutation (SNP) | VAF 55/643 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2
- UCK1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- CNTN4 | c.438G>A p.P146= | Silent (SNP) | VAF 42/734 reads (6%) | catalogued as rs1281255689, COSV68563395; called by muse, mutect2
- DAGLB | c.717C>T p.L239= | Silent (SNP) | VAF 26/582 reads (4%) | catalogued as rs751467052, COSV51706478; called by muse, mutect2
- DNM1L | c.1086T>C p.G362= | Silent (SNP) | VAF 19/301 reads (6%) | called by muse, mutect2
- FNDC1 | c.2553G>A p.S851= | Silent (SNP) | VAF 47/592 reads (8%) | catalogued as rs1441317889, COSV99797375; called by muse, mutect2
- NTF3 | c.762C>T p.I254= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs201630054, COSV58417125; called by muse, mutect2
- CC2D2B | c.780+5032G>A | Intron (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- KCNQ1 | c.1514+4773G>C | Intron (SNP) | VAF 23/399 reads (6%) | called by muse, mutect2
